CCDI case PBCKIA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/90b88f8d-1763-4d8b-b983-b010b67e66d1

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.1 years (51 days).

Biospecimens (3 samples)
- Sample 0DTUX5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DTUX9: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DTUYP: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
